Somatic mutation profile of tumor specimen TCGA-BP-4970-01A (aliquot TCGA-BP-4970-01A-01D-1462-08) from TCGA case TCGA-BP-4970, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 44.4 years (16,228 days).
Specimen TCGA-BP-4970-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 779be35b-a0e0-4fee-ab84-036bc002db42.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BP-4970-11A (Solid Tissue Normal), aliquot TCGA-BP-4970-11A-01D-1462-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/84cc8c9f-ecfc-4d34-a091-8117f5303160

The open-access MAF lists 30 somatic variants for this specimen: 26 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 20, Frame Shift Del 4, Silent 4, Splice Site 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- VHL | c.463+1G>T p.X155_splice | Splice Site (SNP) | VAF 22/141 reads (16%) | hotspot (GDC flag); catalogued as CS004297, CS111451, CS961708, COSV56543633, COSV56544194, COSV56546569, COSV56552736; called by muse, mutect2, varscan2
- ACOT8 | c.409C>A p.Q137K | Missense Mutation (SNP) | VAF 43/188 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.055); catalogued as COSV54170907; called by muse, mutect2, varscan2
- ACSF2 | c.680T>C p.L227P | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV51973900; called by muse, mutect2, varscan2
- COL19A1 | c.1075G>T p.E359* | Nonsense Mutation (SNP) | VAF 14/64 reads (22%) | catalogued as COSV59584253; called by muse, mutect2, varscan2
- CSTF2T | c.1081G>A p.G361S | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV58657337; called by muse, mutect2, varscan2
- DMKN | c.593A>C p.N198T | Missense Mutation (SNP) | VAF 21/100 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.577); catalogued as COSV60088683; called by muse, mutect2, varscan2
- EXOC4 | c.1052C>A p.A351D | Missense Mutation (SNP) | VAF 23/117 reads (20%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.852); catalogued as COSV54116469; called by muse, mutect2, varscan2
- FSCB | c.283G>A p.E95K | Missense Mutation (SNP) | VAF 56/296 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.142); catalogued as COSV100469214, COSV61217375; called by muse, mutect2, varscan2
- HPSE | c.1546del p.L516Sfs*18 | Frame Shift Del (DEL) | VAF 16/125 reads (13%) | catalogued as COSV100264461; called by mutect2, pindel, varscan2
- HSD17B8 | c.626A>G p.K209R | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT tolerated (0.37); PolyPhen benign (0.007); catalogued as COSV63002874; called by muse, mutect2, varscan2
- LRRC15 | c.170G>T p.S57I | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.7); catalogued as COSV61651246; called by muse, mutect2
- MKS1 | c.1598G>A p.R533H | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs779093781, COSV56598661; called by muse, mutect2, varscan2
- MTDH | c.839C>G p.T280S | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.3); PolyPhen benign (0.072); catalogued as COSV60346108; called by muse, mutect2, varscan2
- NT5C1B | c.1369T>C p.Y457H (on ENST00000359846 / NM_001199086.2; = p.Y397H on NM_033253.4) | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.95); catalogued as COSV58398400; called by muse, mutect2, varscan2
- PCDHA2 | c.1508C>T p.A503V | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.797); catalogued as rs782245079, COSV65370325; called by muse, mutect2, varscan2
- POGZ | c.2149C>A p.P717T | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0.01); catalogued as COSV55040747; called by muse, mutect2, varscan2
- PPP3CC | c.711T>G p.N237K | Missense Mutation (SNP) | VAF 50/146 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.014); catalogued as COSV51502981; called by muse, mutect2, varscan2
- PRKAG1 | c.832A>C p.K278Q | Missense Mutation (SNP) | VAF 79/409 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.25); catalogued as COSV60294318; called by muse, mutect2, varscan2
- SF3B2 | c.272C>A p.P91H | Missense Mutation (SNP) | VAF 26/121 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.99); catalogued as COSV59429766; called by muse, mutect2, varscan2
- TAF1C | c.800C>T p.P267L | Missense Mutation (SNP) | VAF 36/153 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV58988695; called by muse, mutect2, varscan2
- TEX26 | c.253G>T p.D85Y | Missense Mutation (SNP) | VAF 26/155 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as COSV66840549; called by muse, mutect2, varscan2
- UBE3C | c.343A>G p.I115V | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as COSV61955224; called by muse, varscan2
- ZBTB38 | c.379T>C p.F127L | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT tolerated (0.45); PolyPhen benign (0.14); catalogued as COSV58543747; called by muse, mutect2, varscan2
- ANKRD17 | c.796del p.E266Kfs*8 | Frame Shift Del (DEL) | VAF 12/106 reads (11%) | called by mutect2, pindel, varscan2
- SOAT2 | c.1338del p.V448Sfs*3 | Frame Shift Del (DEL) | VAF 16/93 reads (17%) | called by mutect2, pindel, varscan2
- UGGT2 | c.1908del p.E637Nfs*2 | Frame Shift Del (DEL) | VAF 32/157 reads (20%) | called by mutect2, pindel, varscan2
- HEATR9 | c.1527A>G p.Q509= | Silent (SNP) | VAF 52/206 reads (25%) | called by muse, mutect2, varscan2
- OSBPL7 | c.672C>T p.I224= | Silent (SNP) | VAF 9/59 reads (15%) | catalogued as rs777315878, COSV50113724; called by muse, varscan2
- PIGU | c.354G>A p.Q118= | Silent (SNP) | VAF 11/77 reads (14%) | catalogued as rs1472545093, COSV54165542; called by muse, mutect2, varscan2
- TRIM5 | c.846A>G p.K282= | Silent (SNP) | VAF 37/140 reads (26%) | catalogued as COSV59901888; called by muse, mutect2, varscan2
